Surgical pathology report (de-identified scan), TCGA case TCGA-H4-A2HO, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-H4-A2HO-01A (Primary Tumor).

[page 1 of 6]
Patient Name:
MRN:
DOB: Sex: Male White
Account Number:
Visit Date:
Discharge date:
Patient Type: Inpatient
Location:
Attending Physician:

Final Pathology Diagnosis Report

Accession Number

Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

Final Pathologic Diagnosis

A) URETHRAL MARGIN (BIOPSY):

- Chronic urethritis, negative for malignancy.

1CD-0-3
Carcinoma, urothelial
(transitional cell), papillary
8130/3

B) LEFT DISTAL URETER #1 (BIOPSY):

- Benign urothelial mucosa, negative for malignancy.

Site: bladder, NOS C67.9

C) RIGHT DISTAL URETER #1 (BIOPSY):

- Benign urothelial mucosa, negative for malignancy.

fw
6/18/11

D) RIGHT PELVIC LYMPH NODE (LYMPH NODE DISSECTION):

- Four benign lymph nodes, negative for malignancy (0/4).

E) LEFT PELVIC LYMPH NODE (LYMPH NODE DISSECTION):

- Four benign lymph nodes, negative for malignancy (0/4).

F) URINARY BLADDER (RADICAL CYSTOPROSTATECTOMY):

- Invasive high-grade urothelial carcinoma (see synoptic report).

[page 2 of 6]
Patient Name:
MRN:
DOB: 7 Sex: Male White
Account Number:
Visit Date: 4
Discharge date:
Patient Type:
Location:
Attending Physician: Te

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

G) RIGHT DISTAL URETER MARGIN #2 (BIOPSY):

- **Benign urothelial mucosa, negative for malignancy.**

H) LEFT DISTAL URETER MARGIN #2 (BIOPSY):

- **Benign urothelial mucosa, negative for malignancy.**

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Electronic Signature
Verified
~~

Resident:

Diagnostic Comment

(Dr.

Deeper sections are examined on blocks A1, C1 and G1.

Synoptic Report

F: Urinary Bladder, Cystectomy

SPECIMEN:

Bladder

PROCEDURE:

Radical cystoprostatectomy

*TUMOR SITE:

*Trigone

*Right lateral wall

*Left lateral wall

*Anterior wall

*Posterior wall

*Dome

Overall, about 95% of bladder mucosa was involved by tumor

TUMOR SIZE:

Printed:

Confidential Information

[page 3 of 6]
Patient Name: :
MRN:
DOB: Sex: Male White
Account Number:
Visit Date
Discharge date
Patient Type:
Location:
Attending Physician:

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

Greatest dimension: 12 cm

*Additional dimensions: 11 x 1.5 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma

HISTOLOGIC GRADE:

High-grade

***TUMOR CONFIGURATION:**

*Papillary

MICROSCOPIC TUMOR EXTENSION (select all that apply):

Prostatic stroma (Tumor involves the prostatic urethra and superficially infiltrates prostatic stroma.)

MARGINS:

Margins uninvolved by invasive carcinoma

*Distance of invasive carcinoma from closest margin: 7 mm

*Specify margin: Serosal radial margin

LYMPH-VASCULAR INVASION:

Not identified

PATHOLOGIC STAGING (pTNM):

PRIMARY TUMOR (pT)

pT4a: Tumor invades prostatic stroma or uterus or vagina (Superficial peri-urethral prostatic stromal invasion as per CAP protocol)

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

Number examined: 8

Number involved: 0

DISTANT METASTASIS (pM)

Not applicable

***ADDITIONAL PATHOLOGIC FINDINGS:**

Urothelial dysplasia (low-grade intraurothelial neoplasia)

Acute and chronic prostatitis

Intraoperative Diagnosis

(Dr.

FS A1: Negative for carcinoma / high grade dysplasia.

FS B1: Negative for carcinoma / high grade dysplasia.

FS C1: Negative for carcinoma / high grade dysplasia.

Printed:

. Confidential Information

[page 4 of 6]
Patient Name:
MRN:
DOB: 5 Male White
Account Number:
Visit Date:
Discharge date:
Patient Type:
Location:
Attending Physician:

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

Clinical History

year-old white male with bladder cancer.

Pre/Post-operative Diagnosis

Bladder cancer.

Gross Anatomic Description

(Dictated by Dr.)

Specimens received in eight containers.

Specimen A: Designated "urethra margins for FS (stitch on bladder end)" is received fresh for intraoperative consultation and frozen section diagnosis on labeled with the patient's name and "urethra margins for FS (stitch on bladder end)". Specimen consists of one piece of red/tan tissue measuring 1.2 x 1.2 x 1.0 cm with a stitch on the bladder end. The entire specimen was frozen.

Inking code: Blue – on stitch end.

Section code: A1 – frozen section control, entire specimen.

Specimen B: Designated "left distal ureter #1 (staple on bladder end)" is received fresh for intraoperative consultation and frozen section diagnosis on labeled with the patient's name and "left distal ureter #1 (staple on bladder end)". Specimen consists of one piece of red/tan tissue measuring 1.2 x 0.8 x 0.8 cm with a staple. The entire specimen was submitted for frozen.

Inking code: Blue – on the margin.

Section code: B1 – frozen section control, entire specimen.

Specimen C: Designated "right distal ureter #1 (stitch on bladder end)" is received fresh for intraoperative consultation and frozen section diagnosis on labeled with the patient's name and "right distal ureter #1 (stitch on bladder end)". Specimen consists of one piece of red/tan tissue measuring 0.8 x 0.7 x 0.6 cm with a suture. The entire specimen was submitted for frozen.

Inking code: Blue – on margin.

Section code: C1 – frozen section control, entire specimen.

Specimen D: Designated "right pelvic lymph node" is received in formalin labeled with the patient's name and "right pelvic lymph node". Specimen consists of a single gray/tan fibrofatty soft tissue material measuring 4.5 x 1.5 x 0.8 cm. Three lymph nodes are identified measuring 3.0 x 1.0 x 0.5 cm, 1.5 x 0.4 x 0.4 cm and 1.0 x 0.3 x 0.3 cm.

Section code: D1 – lymph node #1 and 2, bisected; D2 – lymph node #3 bisected; D3 – remainder of the entire specimen.

Printed:

Confidential Information

[page 5 of 6]
Patient Name:
MRN:
DOB: Sex: Male White
Account Number
Visit Date
Discharge date:
Patient Type:
Location
Attending Physician:

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimen E: Designated "left pelvic lymph node" is received in formalin labeled with the patient's name and "left pelvic lymph node". Specimen consists of a single yellow/tan fibrofatty soft tissue fragment measuring 4.0 x 2.5 x 1.0 cm. Three lymph nodes are identified measuring 3.0 x 0.6 x 0.3 cm, 0.6 x 0.3 x 0.2 cm and 0.5 x 0.3 x 0.2 cm.

Section code: E1 – lymph node #1 and 2, bisected; E2 – lymph node #3, whole; E3 – remainder of the entire specimen.

Specimen F: Designated "bladder" is received fresh labeled with the patient's name and "bladder". Specimen consists of a radical cystoprostatectomy specimen including an intact bladder (7.0 x 6.0 x 6.0 cm) with attached bilateral ureteral stumps measuring 3.5 cm in length and 0.3 cm in diameter (left) and 3.5 cm in length and 0.3 cm in diameter (right) and attached prostate measuring 4.5 x 3.5 x 3.0 cm. There is a gray/tan cauliflower-like tumor covering the entire surface of the bladder measuring 11.0 x 12.0 cm in surface area and 1.2 cm in height. Grossly the tumor does not extend into the serosa / inked margin. It is 1.0 cm from the ureteral opening. The ureteral openings are patent and uninvolved by the tumor. The prostate is white/tan on cut surface with no visible lesions. The seminal vesicles and vas deferens are without tumor or any other abnormality.

Section code: F1 – right ureter resection margin and right vas deferens, en face; F2 – left ureter resection margin and left vas deferens, en face; F3 – tumor full thickness anterior; F4 – tumor full thickness posterior; F5-F7 – tumor full thickness with inked serosal margin; F8-F12 – right prostate and seminal vesicles; F13-F19 – right prostate and seminal vesicles.

Specimen G: Designated "right distal ureter #2 (stitch on bladder end)" is received in formalin labeled with the patient's name and "right distal ureter #2 (stitch on bladder end)". Specimen consists of a single gray/tan piece of ureter measuring 2.5 cm in length and 0.4 cm in diameter.

Section code: G1 – bladder end en face.

Specimen H: Designated "left distal ureter #2 (stitch on bladder end)" is received in formalin labeled with the patient's name and "left distal ureter #2 (stitch on bladder end)". Specimen consists of a single gray/tan piece of ureter measuring 1.1 cm in length and 0.6 cm in diameter.

Section code: H1 – bladder margin en face.

[page 6 of 6]
Patient Name:
MRN:
DOB Sex: Male White
Account Number:
Visit Date
Discharge date
Patient Type
Location
Attending Physician:

I n t r a o p e r a t i v e D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

Intraoperative Diagnosis

(Dr.
FS A1: **Negative for carcinoma / high grade dysplasia.**
FS B1: **Negative for carcinoma / high grade dysplasia.**
FS C1: **Negative for carcinoma / high grade dysplasia.**

Printed:

Confidential Information

Source: NCI Genomic Data Commons file 7ae60243-d0ad-479b-94bd-4cb1ac86bf73 (TCGA-H4-A2HO.24DECC4E-928C-40D2-9269-FE2ABD53E289.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).